Somatic mutation profile of tumor specimen TCGA-YL-A8HJ-01A (aliquot TCGA-YL-A8HJ-01A-11D-A364-08) from TCGA case TCGA-YL-A8HJ, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.6 years (21,416 days).
Specimen TCGA-YL-A8HJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 723864d7-beca-42f1-896f-fbbd52ab28bc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A8HJ-10A (Blood Derived Normal), aliquot TCGA-YL-A8HJ-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ffc8f36-b7dc-4561-a934-ecbab9c0a84f

The open-access MAF lists 32 somatic variants for this specimen: 25 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 24, Silent 7, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTRT1 | c.211C>A p.H71N | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV100947590; called by muse, mutect2
- BRWD3 | c.1242G>T p.L414F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV100956049; called by muse, mutect2, varscan2
- CD200R1L | c.431-2A>G p.X144_splice | Splice Site (SNP) | VAF 11/70 reads (16%) | catalogued as rs1330685486, COSV101236585; called by muse, mutect2, varscan2
- CD96 | c.71A>G p.E24G | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1559707217, COSV99342880; called by muse, mutect2, varscan2
- CFAP47 | c.4840T>C p.S1614P | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.723); catalogued as COSV100545342; called by muse, mutect2, varscan2
- CPNE8 | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.1); catalogued as rs781529622, COSV100504351; called by muse, mutect2, varscan2
- CSMD3 | c.379C>T p.H127Y | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.968); catalogued as rs370667704, COSV52183648; called by muse, mutect2, varscan2
- DDX41 | c.631G>A p.G211S | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100286576; called by muse, mutect2
- EPHA2 | c.1765G>A p.V589M | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs780312721, COSV64453417; called by muse, mutect2, varscan2
- GMIP | c.1900G>A p.V634M | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs780990487, COSV52560988; called by muse, mutect2, varscan2
- IGHV6-1 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs571474919; called by muse, mutect2, varscan2
- KDM3B | c.4699G>A p.V1567I | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as COSV100069628; called by muse, mutect2, varscan2
- MUC5AC | c.14164G>A p.V4722M | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs756204247, COSV100611440; called by muse, mutect2, varscan2
- MYH2 | c.1822G>A p.V608M | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs770151167, COSV55439010, COSV99820105; called by muse, mutect2, varscan2
- NFKBIE | c.952G>A p.A318T (on ENST00000275015; = p.A179T on NM_004556.3) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99241105; called by muse, mutect2, varscan2
- PCDH17 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs745877167, COSV100931636; called by muse, mutect2, varscan2
- PRKACA | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.61); catalogued as rs1408895901, COSV100432031; called by muse, mutect2, varscan2
- QSOX1 | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs764868665, COSV62581475; called by muse, mutect2, varscan2
- RYR1 | c.7021G>A p.V2341I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.398); catalogued as rs767615522, COSV62089431; called by muse, mutect2, varscan2
- SMPD2 | c.232A>T p.I78F | Missense Mutation (SNP) | VAF 34/207 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV99237975; called by muse, mutect2, varscan2
- TSHZ3 | c.2909A>G p.D970G | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99551542; called by muse, mutect2
- UTRN | c.9836T>C p.V3279A | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV100838535; called by muse, mutect2, varscan2
- XPOT | c.2057C>A p.T686K | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV100225517; called by muse, mutect2
- ZBTB16 | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.885); catalogued as rs1565705590, COSV100251484, COSV60098140; called by muse, mutect2, varscan2
- ZNF587 | c.1357G>T p.V453F | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.164); catalogued as rs780214597, COSV100299479; called by muse, mutect2, varscan2
- ABCA4 | c.2634G>A p.S878= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as rs755162138, COSV64676820; called by muse, mutect2, varscan2
- FFAR3 | c.117C>T p.F39= | Silent (SNP) | VAF 17/137 reads (12%) | catalogued as rs148149328, COSV100588087; called by muse, mutect2, varscan2
- MAGEA6 | c.906A>T p.P302= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs1556836860, COSV100262818; called by muse, mutect2, varscan2
- MEGF6 | c.924G>A p.K308= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV99620335; called by muse, mutect2, varscan2
- SLC12A5 | c.2727G>A p.A909= (on ENST00000454036 / NM_001134771.2; = p.A886= on NM_020708.5) | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs546939045, COSV54792989; called by muse, mutect2, varscan2
- SUPT6H | c.2361C>A p.S787= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV100112409; called by muse, mutect2
- TRIL | c.180C>T p.D60= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV100538814; called by muse, mutect2, varscan2
